Somatic mutation profile of tumor specimen TCGA-FX-A3NJ-01A (aliquot TCGA-FX-A3NJ-01A-11D-A21Q-09) from TCGA case TCGA-FX-A3NJ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 54.5 years (19,903 days).
Specimen TCGA-FX-A3NJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64f03fe4-5ab5-487a-b10f-341c1db3f442.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FX-A3NJ-10A (Blood Derived Normal), aliquot TCGA-FX-A3NJ-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93ec2e5c-57ea-4e25-8192-1e55fb41f57d

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP2A6 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.572); catalogued as rs1465959396, COSV99991835; called by muse, mutect2
- PLD5 | c.1606G>C p.V536L (on ENST00000442594; = p.V474L on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/130 reads (52%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV99043081; called by muse, mutect2, varscan2
- RGS2 | c.4C>T p.Q2* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as rs760672186, COSV52459588; called by muse, mutect2, varscan2
- SLC6A12 | c.1093A>G p.I365V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs774963088, COSV100675075; called by muse, mutect2, varscan2
- ACADSB | c.412T>G p.F138V | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BCLAF1 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRY1 | c.681A>T p.R227S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.196); called by muse, mutect2
- GC | c.1217T>G p.L406R | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IL17RA | c.2375C>A p.S792Y | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- INTS3 | c.1499C>G p.P500R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PLOD3 | c.1294del p.L432* | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | called by mutect2, pindel, varscan2
- TAF6L | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ABCA13 | c.13920C>T p.F4640= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs769165172, COSV68947855; called by muse, mutect2, varscan2
- ANK3 | c.6870G>C p.L2290= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- GNPAT | c.1812C>T p.V604= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as rs1192186321, COSV64153603; called by muse, mutect2, varscan2
- MUC4 | c.1905C>T p.S635= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as rs768537191, COSV100642478; called by muse, mutect2, varscan2
- RTL10 | c.279G>A p.R93= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs751425423; called by muse, mutect2, varscan2
